Somatic mutation profile of tumor specimen TARGET-10-PANVIX-09A (aliquot TARGET-10-PANVIX-09A-01D) from TARGET case TARGET-10-PANVIX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (618 days).
Specimen TARGET-10-PANVIX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc56b856-70c2-45f2-90f6-44cb74b9cb7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVIX-10A (Blood Derived Normal), aliquot TARGET-10-PANVIX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31373ce9-5ea0-4367-8b6f-d528f2adf35a

The open-access MAF lists 23 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Nonsense Mutation 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHEX | c.2140C>T p.Q714* | Nonsense Mutation (SNP) | VAF 16/399 reads (4%) | catalogued as rs1569442206, COSV65074178; ClinVar: likely pathogenic; called by muse, mutect2
- DIRAS3 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.893); catalogued as COSV100921307; called by muse, mutect2, varscan2
- HMX1 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397306867, COSV68772038, COSV68772073; called by muse, mutect2, varscan2
- ABCA6 | c.954G>T p.M318I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.14); called by muse, mutect2
- ATXN1 | c.2175G>T p.E725D | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); called by muse, mutect2
- BBS7 | c.121G>C p.D41H | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2
- BCL6 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | called by mutect2, varscan2
- BSX | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- JAG2 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KRTAP29-1 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- NOSTRIN | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RNF115 | c.229C>A p.H77N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- SLC28A2 | c.1973C>A p.A658D | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.812); called by mutect2, varscan2
- TMC7 | c.955A>C p.N319H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); called by muse, varscan2
- EHMT2 | c.2142G>T p.V714= | Silent (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- NODAL | c.1041C>G p.L347= | Silent (SNP) | VAF 78/293 reads (27%) | called by muse, mutect2, varscan2
- OR8B12 | c.768C>T p.F256= | Silent (SNP) | VAF 11/146 reads (8%) | called by muse, mutect2
- PSG3 | c.348C>T p.D116= | Silent (SNP) | VAF 42/153 reads (27%) | catalogued as rs772450674, COSV100549348; called by muse, mutect2, varscan2
- PXDNL | c.2190C>T p.H730= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100687450; called by muse, mutect2, varscan2
- RIMS2 | c.960C>T p.Y320= (on ENST00000666250 / NM_001348490.2; = p.Y128= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs200152573, COSV51715692; called by mutect2, varscan2
- TTC3 | c.5730G>A p.R1910= | Silent (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- DAP | c.*55C>G | 3'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- TXNRD3 | n.821G>T | RNA (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
